CCDI case PBBPWU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/743ad228-ed66-4174-9771-7f4abbd1c102

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, mixed forms: ICD-O-3 morphology code: 8592/1; Tissue or organ of origin: Ovary; Age at diagnosis: 13.8 years (5,043 days).

Biospecimens (3 samples)
- Samples 0DER0C, 0DF6VE (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DER0P: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
